Gene-level copy-number profile of tumor specimen ALCH-B25C-TTP1-A from ALCHEMIST case ALCH-B25C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.7 years (24,723 days).
Specimen ALCH-B25C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 97ae833a-7390-4ef5-9fc5-1a84c450450f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B25C-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,262 have no estimate.
https://portal.gdc.cancer.gov/files/06ae6c2d-af9e-4b8a-b66b-565dc88da80e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 1,607; copy number 2: 50,766; copy number 3: 5,134; copy number 4: 588; copy number 5: 162; copy number 6: 4; copy number 7: 1; copy number 8: 69; copy number 10: 11.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–14,409, 1 gene: DDX11L1.
- chr1:65,419–133,723, 3 genes (within-gene range 0–2): OR4F5, AL627309.1, AL627309.3.
- chr1:257,864–522,928, 10 genes (within-gene range 0–2): AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:587,629–594,768, 1 gene: AC114498.1.
- chr17:2,689,386–2,712,663, 2 genes (within-gene range 0–2): CLUH, MIR6776.
- chr17:30,624,413–30,637,466, 2 genes (within-gene range 0–2): SH3GL1P2, LRRC37BP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 247 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,554–36,081, 1 gene, copy number 6: FAM138A.
- chr1:143,874,793–143,883,575, 1 gene, copy number 5: FCGR1CP.
- chr3:168,249,522–168,830,599, 1 gene, copy number 5 (within-gene range 4–5): EGFEM1P.
- chr3:168,475,198–169,663,775, 9 genes, copy number 5 (within-gene range 4–5): RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM.
- chr3:182,588,093–183,463,201, 23 genes, copy number 5: AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3.
- chr7:54,330,670–57,020,273, 86 genes, copy number 5–8 (broad region; genes not listed).
- chr8:132,775,358–132,848,807, 3 genes, copy number 5: PHF20L1, AF230666.2, AF230666.1.
- chr9:42,921,443–43,045,120, 6 genes, copy number 5: CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1.
- chr12:65,466,820–65,663,299, 5 genes, copy number 5 (within-gene range 3–5): AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3.
- chr12:67,065,018–69,823,204, 68 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr14:95,086,228–95,158,010, 2 genes, copy number 5 (within-gene range 2–5): DICER1, MIR3173.
- chr18:21,529,284–23,026,488, 39 genes, copy number 5–10 (within-gene range 2–10): ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741.
- chr22:18,906,028–18,947,732, 3 genes, copy number 6 (within-gene range 2–6): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 1,599. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
